Somatic mutation profile of tumor specimen ER-AE8R-TTP1-A (aliquot ER-AE8R-TTP1-A-1-0-D-A593-34) from EXCEPTIONAL_RESPONDERS case ER-AE8R, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell carcinoma; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 49.4 years (18,031 days).
Specimen ER-AE8R-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cd44726-9118-4d05-87b4-addf253268c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-AE8R-NT1-A (Solid Tissue Normal), aliquot ER-AE8R-NT1-A-1-0-D-A593-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60eac57a-407c-4c00-ba85-6ee302a006bb

The open-access MAF lists 60 somatic variants for this specimen: 48 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 8, Nonsense Mutation 3, Frame Shift Del 2, Intron 2, Splice Site 1, 5'UTR 1, 3'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC3 | c.2158T>C p.Y720H | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1458690598; called by muse, mutect2, varscan2
- ACAD11 | c.1522+1G>T p.X508_splice | Splice Site (SNP) | VAF 25/102 reads (25%) | catalogued as rs556222225; called by muse, mutect2, varscan2
- APC2 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1456528609; called by muse, mutect2
- BAP1 | c.620G>C p.R207P | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56243970; called by muse, mutect2, varscan2
- BRCA2 | c.5188A>T p.N1730Y | Missense Mutation (SNP) | VAF 32/327 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.782); catalogued as rs397507770, CM010168; ClinVar: not provided; called by muse, mutect2, varscan2
- CDKN2A | c.216C>A p.C72* | Nonsense Mutation (SNP) | VAF 10/96 reads (10%) | catalogued as CM127042, COSV58683179, COSV58691985, COSV58722986; called by muse, mutect2
- FGF14 | c.148G>T p.G50* | Nonsense Mutation (SNP) | VAF 11/88 reads (13%) | catalogued as COSV101086782; called by muse, mutect2, varscan2
- GCNT4 | c.880del p.H294Ifs*14 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as rs768450027; called by pindel, varscan2
- GRPR | c.767T>C p.I256T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as rs1271915830; called by muse, mutect2, varscan2
- KIAA1522 | c.1327C>T p.R443C (on ENST00000373480 / NM_001198972.2; = p.R502C on NM_020888.3) | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs766963606; called by muse, mutect2, varscan2
- PLS3 | c.1796G>C p.R599T | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV56780025, COSV56782140; called by muse, mutect2
- PPP3R1 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 67/530 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV52249948; called by muse, mutect2, varscan2
- USP54 | c.4784C>T p.S1595F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.127); catalogued as rs770823331; called by muse, mutect2, varscan2
- AGAP2 | c.3418G>A p.A1140T (on ENST00000547588 / NM_001122772.2; = p.A784T on NM_014770.4) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.212); called by muse, mutect2
- ARHGAP45 | c.2519T>C p.L840P | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC42BPB | c.1673C>A p.S558Y | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- CSTF3 | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCSTAMP | c.1167G>T p.M389I | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- DUSP1 | c.454A>G p.S152G | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF4G3 | c.3349C>A p.P1117T | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2
- FANCB | c.970_972dup p.K324dup | In Frame Ins (INS) | VAF 73/619 reads (12%) | called by mutect2, pindel
- FLNB | c.3798C>G p.I1266M | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- GPR155 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- HSPA1L | c.759G>T p.K253N | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ICA1 | c.789A>T p.E263D | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- LILRA2 | c.1017C>A p.N339K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- MSX2 | c.545C>G p.T182R | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MYO3B | c.831T>A p.D277E | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- NNT | c.1928C>T p.T643I | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PDSS1 | c.689T>C p.I230T | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PPP1R15B | c.661T>C p.Y221H | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTPN1 | c.584T>C p.L195P | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRQ | c.3950T>G p.V1317G (on ENST00000616559; = p.V1275G on NM_001145026.2) | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2
- RADX | c.1559G>C p.S520T | Missense Mutation (SNP) | VAF 27/427 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2
- RUFY2 | c.1499A>C p.K500T | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- SETDB1 | c.3762A>C p.R1254S (on ENST00000271640 / NM_001366417.1; = p.K1253N on NM_012432.4) | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, varscan2
- THBS3 | c.787A>G p.I263V | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.123); called by muse, mutect2
- TLK2 | c.449T>G p.M150R | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.018); called by muse, mutect2
- TMEM176B | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNRC18 | c.5563G>T p.A1855S | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- TUFT1 | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 28/187 reads (15%) | called by muse, mutect2, varscan2
- UBN2 | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 40/416 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- USH2A | c.9326C>A p.T3109N | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- UTP4 | c.250A>G p.M84V | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZC3H3 | c.751T>C p.S251P | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2
- ZDHHC6 | c.118A>C p.I40L | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF184 | c.1021A>G p.K341E | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- ZNF529 | c.1286_1290del p.K429Ifs*5 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | called by mutect2, pindel, varscan2
- ABCA13 | c.11766G>A p.Q3922= | Silent (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- ACTN4 | c.1521T>G p.S507= | Silent (SNP) | VAF 22/144 reads (15%) | called by muse, mutect2, varscan2
- CCDC110 | c.316C>T p.L106= | Silent (SNP) | VAF 24/158 reads (15%) | catalogued as COSV56870513; called by muse, mutect2, varscan2
- MAMDC4 | c.2658T>C p.P886= (on ENST00000445819; = p.P807= on NM_206920.3) | Silent (SNP) | VAF 9/107 reads (8%) | called by muse, mutect2
- PCDHGB5 | c.1419G>A p.S473= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV53894274; called by muse, mutect2, varscan2
- SAV1 | c.174T>C p.N58= | Silent (SNP) | VAF 32/189 reads (17%) | called by muse, mutect2, varscan2
- TRAFD1 | c.1212T>C p.I404= | Silent (SNP) | VAF 10/111 reads (9%) | called by muse, mutect2
- WDFY4 | c.7695T>C p.N2565= | Silent (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- FAF2 | c.-9G>A | 5'UTR (SNP) | VAF 31/189 reads (16%) | catalogued as rs1183926930; called by muse, mutect2, varscan2
- GFOD1 | c.253+16611C>A | Intron (SNP) | VAF 9/121 reads (7%) | catalogued as rs1484825897; called by muse, mutect2
- GFOD1 | c.253+16610T>A | Intron (SNP) | VAF 10/121 reads (8%) | catalogued as COSV64953098; called by muse, mutect2
- KRTAP9-3 | c.*374del | 3'UTR (DEL) | VAF 8/81 reads (10%) | called by mutect2, pindel, varscan2
